Gene-level copy-number profile of tumor specimen TCGA-DD-A39X-01A from TCGA case TCGA-DD-A39X, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.1 years (28,528 days).
Specimen TCGA-DD-A39X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.348cc5ed-b96a-4dd4-b639-f5da7af4fe3c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A39X-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98dc388f-d0e2-448d-9be5-2c802023b041

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 810; copy number 2: 7,390; copy number 3: 20,498; copy number 4: 26,207; copy number 5: 2,368; copy number 7: 540; copy number 8: 267; copy number 9: 18; copy number 12: 1,720.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A39X-01A-11D-A20V-01): tumor purity 0.6, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:27,172,259–27,182,998, 1 gene: USP12-AS2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,738 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–169,103,276, 995 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr8:99,013,266–145,066,685, 725 genes, copy number 12 (broad region; genes not listed).
- chr13:61,805,150–63,097,797, 12 genes, copy number 9 (within-gene range 1–9): RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1.
- chr19:6,135,247–6,279,975, 6 genes, copy number 9 (within-gene range 2–9): ACSBG2, AC011471.1, AC011471.4, MLLT1, AC011471.2, AC011471.3.

Autosomal genes at a single copy (total copy number 1): 810. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
